Somatic mutation profile of tumor specimen C3L-01929-01 (aliquot CPT0093020009) from CPTAC case C3L-01929, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.9 years (19,698 days).
Specimen C3L-01929-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6db52462-432f-4efc-98b1-8f27714eed84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01929-31 (Blood Derived Normal), aliquot CPT0092450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b17c2d6-6e8e-4945-a814-6bc3cb1e9ec5

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 10 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 10, Intron 6, 3'UTR 3, RNA 2, Nonsense Mutation 2, Frame Shift Ins 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HUWE1 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1057518704, COSV53343772; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.263G>C p.W88S | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs119103277, CM951277, CM995326, HX971376, COSV56543204, COSV56545932, COSV56566114; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.2698A>G p.M900V | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV51686512; called by muse, mutect2, varscan2
- CBFA2T3 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs553618592, COSV51922457; called by muse, mutect2
- FAM110C | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767039777; called by muse, mutect2
- FBN1 | c.7141C>A p.Q2381K | Missense Mutation (SNP) | VAF 46/562 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as CM098619; called by muse, mutect2
- GAPDH | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.078); catalogued as rs11549361; called by muse, mutect2, varscan2
- GPR17 | c.599C>G p.T200S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.696); catalogued as COSV55757105; called by muse, mutect2, varscan2
- MGAM | c.4990C>T p.P1664S | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767688894; called by muse, mutect2, varscan2
- MRTFA | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100843918; called by muse, mutect2
- OR13C2 | c.508A>T p.R170W | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101604895; called by muse, mutect2
- PCDHGA3 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53902230; called by muse, mutect2, varscan2
- RXFP2 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs117847923; called by muse, mutect2
- RYK | c.1712C>A p.P571H (on ENST00000620660 / NM_001005861.2; = p.P568H on NM_002958.4) | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938538; called by muse, mutect2, varscan2
- SHPRH | c.4717C>T p.R1573C (on ENST00000275233 / NM_001042683.3; = p.R1577C on NM_173082.3) | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs771193142; called by muse, mutect2
- TNFRSF21 | c.1057A>T p.M353L | Missense Mutation (SNP) | VAF 51/533 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs1389359616, COSV57282759; called by muse, mutect2, varscan2
- UBA5 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778957097, COSV53905807; called by muse, mutect2
- UNC45B | c.888G>C p.R296S | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52098279; called by muse, mutect2
- USP53 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs562373380, COSV56793520; called by muse, mutect2
- ZNF429 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.722); catalogued as COSV61917809; called by muse, mutect2
- ACTA1 | c.524A>T p.H175L | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ATMIN | c.360A>G p.I120M | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- BAP1 | c.1966A>T p.K656* | Nonsense Mutation (SNP) | VAF 63/615 reads (10%) | called by muse, mutect2, varscan2
- CCPG1 | c.1980T>G p.I660M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP112 | c.1762G>C p.V588L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.913); called by muse, mutect2
- CPA3 | c.299T>A p.I100N | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- EFCAB3 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.221); called by muse, mutect2
- ENPP2 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2
- FOXO6 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- GBP5 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GUCY2F | c.2424G>C p.Q808H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2
- HEATR1 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- IGF2BP2 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2
- LAMA1 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- LPIN2 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 44/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCF2L | c.1468G>A p.D490N (on ENST00000375608; = p.D458N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- NAE1 | c.678_679dup p.S227Ifs*21 | Frame Shift Ins (INS) | VAF 16/186 reads (9%) | called by mutect2, pindel
- NCKAP5L | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- OR13D1 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PCDHB3 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.402); called by muse, mutect2
- PCSK5 | c.2173C>A p.P725T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2
- PROS1 | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2
- RANGAP1 | c.602C>A p.A201E | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- RPUSD4 | c.1070G>C p.R357P | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2
- SLC52A1 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by mutect2, varscan2
- SMO | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SNRK | c.737T>C p.I246T | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE3 | c.2857dup p.C953Lfs*45 | Frame Shift Ins (INS) | VAF 45/451 reads (10%) | called by mutect2, pindel, varscan2
- TBC1D8B | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL1 | c.1288A>G p.R430G | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- UNC45B | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNKL | c.2042A>G p.D681G (on ENST00000389221 / NM_001372107.1; = p.D177G on NM_001276414.2) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- WTIP | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- XYLT2 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 32/405 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.099); called by muse, mutect2
- ACBD4 | c.702C>T p.F234= (on ENST00000376955 / NM_001378111.1; = p.R238* on NM_024722.4) | Silent (SNP) | VAF 26/408 reads (6%) | catalogued as rs772269471, COSV58851119; called by muse, mutect2
- ADAMTS2 | c.1989G>A p.E663= | Silent (SNP) | VAF 38/462 reads (8%) | called by muse, mutect2
- BCKDK | c.1192C>T p.L398= | Silent (SNP) | VAF 29/327 reads (9%) | called by muse, mutect2
- CPLANE1 | c.8859G>A p.L2953= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- GSTA5 | c.306G>A p.L102= | Silent (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- HEXA | c.720G>A p.K240= | Silent (SNP) | VAF 26/438 reads (6%) | called by muse, mutect2
- MICAL1 | c.414C>G p.L138= | Silent (SNP) | VAF 36/311 reads (12%) | called by muse, mutect2, varscan2
- OGFRL1 | c.45C>G p.T15= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- SETBP1 | c.1857C>T p.G619= | Silent (SNP) | VAF 54/494 reads (11%) | catalogued as COSV56313367; called by muse, mutect2, varscan2
- SLC40A1 | c.1569C>A p.L523= | Silent (SNP) | VAF 59/563 reads (10%) | catalogued as COSV99656118; called by muse, mutect2, varscan2
- ASCC1 | c.*441C>G | 3'UTR (SNP) | VAF 54/598 reads (9%) | called by muse, mutect2
- KLC2 | c.*376C>T | 3'UTR (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2, varscan2
- LEPROT | c.16+717T>G | Intron (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- LGI1 | c.287+39A>G | Intron (SNP) | VAF 25/211 reads (12%) | called by muse, varscan2
- MCCC2 | c.903+44A>C | Intron (SNP) | VAF 61/456 reads (13%) | called by muse, mutect2, varscan2
- MGAT4FP | n.1117G>A | RNA (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21495690 G>C | 3'Flank (SNP) | VAF 47/498 reads (9%) | called by muse, mutect2
- MPRIP | c.*735T>C | 3'UTR (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- MRPL3 | c.630-7916C>G | Intron (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- RNF213 | c.11201-38G>A | Intron (SNP) | VAF 24/341 reads (7%) | called by muse, mutect2
- TLCD2 | chr17:1712346 G>A | 5'Flank (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- TXLNGY | n.5049C>T | RNA (SNP) | VAF 57/244 reads (23%) | called by muse, mutect2, varscan2
- VAC14 | c.1160+3247C>T | Intron (SNP) | VAF 14/160 reads (9%) | catalogued as rs940258397; called by muse, mutect2
